Gene-level copy-number profile of tumor specimen TCGA-2G-AAGT-01A from TCGA case TCGA-2G-AAGT, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 30.0 years (10,967 days).
Specimen TCGA-2G-AAGT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.4be646a9-c9e4-4d17-90c3-906e6ac9cca2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAGT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/674e0cf7-35b9-4a79-a01a-0f5be0a13a52

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,393; copy number 2: 39,844; copy number 3: 15,723; copy number 4: 1,849; copy number 7: 885; copy number 12: 54; copy number 13: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAGT-01A-11D-A42X-01): tumor purity 0.81, ploidy 2.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,005 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–42,686,701, 919 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr12:67,989,445–68,234,686, 1 gene, copy number 13 (within-gene range 2–13): IFNG-AS1.
- chr12:68,143,318–71,927,248, 85 genes, copy number 7–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,393. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
